Gene-level copy-number profile of tumor specimen TCGA-13-0887-01A from TCGA case TCGA-13-0887, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.9 years (15,669 days).
Specimen TCGA-13-0887-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.616b58ea-28e5-4d0c-aa5f-0f08a0c587f3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-13-0887-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1743a501-0845-4d72-9800-3159d3d20fc4

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 871; copy number 2: 17,594; copy number 3: 15,662; copy number 4: 20,063; copy number 5: 1,803; copy number 6: 3,199; copy number 7: 529; copy number 8: 56; copy number 10: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-13-0887-01A-01D-0399-01): tumor purity 0.91, ploidy 1.84, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 8 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:163,042,557–163,137,775, 2 genes: PACRG-AS2, AL137182.1.
- chr10:86,749,754–86,756,298, 1 gene: AC067750.1.
- chr16:72,973,374–73,062,316, 5 genes: AC132068.1, AC002044.3, AC002044.1, AC002044.2, AC116667.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 11 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:62,302,093–62,447,677, 11 genes, copy number 10: ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1.

Autosomal genes at a single copy (total copy number 1): 871. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
